TARGET case TARGET-20-PAYKGV-Sorted-CD34 — Acute Myeloid Leukemia (TARGET-AML)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Myeloid Leukemias; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/555e5cab-cf3a-419c-880d-a9707b96af58

Demographics
Sex at birth: male; Age at index: 4 years; Vital status: Alive.

Diagnoses (1)
1. Acute myeloid leukemia, NOS: ICD-O-3 morphology code: 9861/3; ICD-10 code: C92.0; Tissue or organ of origin: Bone marrow; Classification of tumor: primary; Age at diagnosis: 5.0 years (1,812 days); Year of diagnosis: 2017; Days to last follow up: 6 days; Sites of involvement: Central nervous system.
   Treatment given: Reason treatment ended: Course of Therapy Completed; Course number: 2; Timepoint category: End of Treatment Course.
   Treatment given: Protocol identifier: AAML1031.
   Treatment given: Reason treatment ended: Course of Therapy Completed; Course number: 1; Timepoint category: End of Treatment Course.

Follow-up (1 entry)
- Days to follow up: 6 days; Event-free: no event (relapse, second malignancy or death) recorded through day 6; Year of follow up: 2017.

Molecular and laboratory tests (laboratory values grouped by visit day)
- CEBPA mutation, nos: Negative.
- FLT3 internal tandem duplication: Negative.
- KMT2A translocation: Negative.
- Monosomy 5: Negative.
- Monosomy 7: Negative.
- NPM1 mutation, nos: Negative.
- Test: Negative.
- Test: Negative; Chromosomal translocation: t(10;11)(p11.2;q23).
- Test: Negative; Chromosomal translocation: t(11;19)(q23;p13.1).
- Test: Negative; Chromosomal translocation: t(3;5)(q25;q34).
- Test: Negative; Chromosomal translocation: t(6;11)(q27;q23).
- Test: Negative; Chromosomal translocation: t(6;9).
- Test: Negative; Chromosomal translocation: t(8;21).
- Test: Negative; Chromosomal translocation: t(9;11)(p22;q23).
- Test: Negative; Chromosome arm: q.
- Test: Positive.
- Trisomy 21: Negative.
- Trisomy 8: Negative.
- Day 0: Leukocytes 89.2 ×10³/µL; Blast Count 43.4%.

Biospecimens (1 sample)
- Sample TARGET-20-PAYKGV-Sorted-CD34pos-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
